Somatic mutation profile of tumor specimen TCGA-17-Z042-01A (aliquot TCGA-17-Z042-01A-01W-0746-08) from TCGA case TCGA-17-Z042, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z042-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8c0f5da-a42f-4276-8ee7-55b5b071f099.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z042-11A (Solid Tissue Normal), aliquot TCGA-17-Z042-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/259a728a-4631-4fb7-8476-0e26bb956954

The open-access MAF lists 511 somatic variants for this specimen: 387 protein-altering or splice-affecting, 110 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 328, Silent 110, Nonsense Mutation 37, Splice Site 10, Frame Shift Del 8, RNA 6, Intron 4, 3'UTR 3, Frame Shift Ins 2, Splice Region 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STAT3 | c.1229A>G p.H410R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52885189; called by muse, mutect2, varscan2
- TP53 | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1358G>T p.R453L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748139483, COSV52708864; called by muse, mutect2, varscan2
- ACSM2B | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61657538; called by muse, mutect2, varscan2
- ADAMTS12 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs552049994; called by muse, mutect2, varscan2
- ADAMTS18 | c.2117C>A p.P706H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV51419910; called by muse, mutect2, varscan2
- ADAMTSL1 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV52819643; called by muse, mutect2
- ADD1 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1359559390, COSV53266827; called by muse, mutect2, varscan2
- ADGRL3 | c.952C>A p.H318N (on ENST00000506720 / NM_001322402.2; = p.H250N on NM_015236.6) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72273134; called by muse, mutect2, varscan2
- ADH1B | c.390G>T p.R130S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1026817832; called by muse, mutect2, varscan2
- ALG14 | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs761334440; called by muse, mutect2, varscan2
- ANK2 | c.2713G>T p.D905Y | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs759275920, COSV52169096; called by muse, mutect2, varscan2
- ANO4 | c.2162G>A p.G721E (on ENST00000392977 / NM_001286615.2; = p.G686E on NM_178826.4) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344174898, COSV100153886; called by muse, mutect2, varscan2
- AP1B1 | c.2125G>T p.V709L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.065); catalogued as COSV100434914; called by mutect2, varscan2
- BOC | c.1207G>C p.V403L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV56349043; called by muse, mutect2
- BOD1L1 | c.808G>C p.G270R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV50037544, COSV50086757; called by muse, mutect2, varscan2
- BRCA1 | c.3334G>T p.E1112* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as CD961838, COSV104398344; called by muse, mutect2, varscan2
- C4orf50 | c.292G>T p.E98* (on ENST00000324058; = p.E1330* on NM_001364689.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100135792; called by muse, mutect2, varscan2
- CACNG3 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as rs749946987, COSV50066262; called by muse, mutect2, varscan2
- CADM2 | c.690G>T p.K230N (on ENST00000407528 / NM_001167674.2; = p.K232N on NM_153184.4) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV67359177; called by muse, mutect2, varscan2
- CAPSL | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1189763306; called by muse, mutect2, varscan2
- CCDC180 | c.4612C>T p.P1538S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs1365826756, COSV100826515; called by muse, mutect2, varscan2
- CDH11 | c.1116C>G p.I372M | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs202106531, COSV51762534; called by muse, mutect2, varscan2
- CDH12 | c.1122C>G p.S374R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as COSV101201458, COSV66431812; called by muse, mutect2, varscan2
- CDH20 | c.2080G>T p.A694S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.028); catalogued as rs770570723, COSV53009369, COSV99406664; called by muse, mutect2, varscan2
- CDH26 | c.681A>G p.I227M | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs1352990019; called by muse, mutect2, varscan2
- CHD7 | c.1392G>T p.M464I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.042); catalogued as rs780392912; called by muse, mutect2, varscan2
- CHGB | c.1838A>G p.Y613C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766702026; called by muse, mutect2, varscan2
- CLDN14 | c.620C>A p.T207N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV59772774; called by muse, mutect2
- CLEC9A | c.677C>A p.T226K | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100191438; called by muse, mutect2, varscan2
- CLMP | c.488T>A p.V163E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as COSV71649896; called by muse, mutect2, varscan2
- CNMD | c.867C>A p.S289R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1312706301; called by muse, mutect2, varscan2
- CNTNAP4 | c.3200C>A p.S1067Y | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271815, COSV56671209; called by muse, mutect2, varscan2
- COL15A1 | c.1224A>T p.L408F | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.282); catalogued as COSV66643851; called by muse, mutect2, varscan2
- COL19A1 | c.3302C>A p.A1101D | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs753501507, COSV59577484; called by muse, mutect2, varscan2
- COL22A1 | c.2561C>T p.T854I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.599); catalogued as rs1410342713; called by muse, mutect2, varscan2
- COL3A1 | c.4143G>T p.Q1381H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1029608155; called by muse, mutect2, varscan2
- COL6A3 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as rs749985039; called by muse, mutect2, varscan2
- CPED1 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs757025021; called by muse, mutect2, varscan2
- CPS1 | c.1391C>A p.P464Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826143; called by muse, mutect2, varscan2
- CSMD3 | c.5731C>A p.H1911N (on ENST00000297405 / NM_001363185.1; = p.H1807N on NM_052900.3) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs1161772638, COSV52299174; called by muse, mutect2, varscan2
- CSMD3 | c.4730G>T p.W1577L (on ENST00000297405 / NM_001363185.1; = p.W1473L on NM_052900.3) | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99820805; called by muse, mutect2, varscan2
- CTTNBP2 | c.1196C>A p.P399H | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV50411656; called by muse, mutect2, varscan2
- CUBN | c.4544A>T p.Q1515L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as rs1335854766; called by muse, mutect2, varscan2
- CXXC1 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1434201695, COSV53275066; called by muse, mutect2, varscan2
- DAB1 | c.1267G>C p.V423L (on ENST00000371231; = p.V390L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV64697791; called by muse, mutect2, varscan2
- DCAF4L2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1160347234, COSV60479615, COSV60480142; called by muse, mutect2, varscan2
- DCDC1 | c.2774C>A p.P925H (on ENST00000597505 / NM_001367979.1; = p.P32H on NM_020869.3) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV60308056; called by muse, mutect2, varscan2
- DDR2 | c.2048G>C p.S683T | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV63373348; called by muse, mutect2, varscan2
- DNMT3A | c.2126C>T p.P709L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99261899; called by muse, mutect2, varscan2
- DST | c.14525A>G p.Q4842R (on ENST00000361203 / NM_001374722.1; = p.Q2430R on NM_015548.5) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs1381795345; called by muse, mutect2
- ELF1 | c.1497G>C p.L499F | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs1389961820; called by muse, mutect2, varscan2
- ENAM | c.3188C>G p.A1063G | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV68535808; called by muse, mutect2, varscan2
- ENKUR | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754241618; called by muse, mutect2, varscan2
- EPRS1 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs1224722095; called by muse, mutect2, varscan2
- FAM114A1 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as rs1476985001, COSV62672180; called by muse, mutect2, varscan2
- FAM171A1 | c.1830G>T p.E610D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as rs1265540037; called by muse, mutect2, varscan2
- FAT1 | c.5450A>G p.H1817R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.038); catalogued as rs895831075; called by muse, mutect2, varscan2
- FAT3 | c.11047G>A p.D3683N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as rs1474692373; called by muse, mutect2, varscan2
- FBN3 | c.4619C>A p.T1540N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as rs1301895629; called by muse, mutect2, varscan2
- FER | c.1828A>T p.K610* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as rs1165444869; called by muse, mutect2
- FLG2 | c.4634G>T p.G1545V | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV101166208; called by muse, mutect2, varscan2
- GABRA2 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs200604169; called by muse, mutect2, varscan2
- GJA4 | c.523C>A p.R175S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV60725408; called by muse, mutect2, varscan2
- GLDC | c.830C>A p.T277K | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.02); catalogued as COSV58678724; called by muse, mutect2, varscan2
- GLG1 | c.810G>T p.L270F | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52663999; called by muse, mutect2, varscan2
- GOLM2 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV55461368; called by muse, mutect2, varscan2
- GPR85 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51782998; called by muse, mutect2, varscan2
- GRIN2B | c.312C>A p.D104E | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1389567704; called by muse, mutect2, varscan2
- HMCN1 | c.10298C>A p.P3433Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1489686504, COSV99630081; called by muse, mutect2, varscan2
- IARS1 | c.2900C>T p.A967V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV65112901; called by muse, mutect2, varscan2
- IDE | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56423367; called by muse, mutect2, varscan2
- IDH3B | c.54del p.N19Tfs*8 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | catalogued as rs1467491634, COSV101077098; called by mutect2, pindel, varscan2
- IGKV2D-24 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs769748347; called by muse, mutect2, varscan2
- IL18RAP | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs986656578, COSV51825925; called by muse, mutect2, varscan2
- ITGAM | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs1273983250; called by muse, mutect2, varscan2
- ITIH4 | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1301808702; called by muse, mutect2, varscan2
- IZUMO1R | c.464G>A p.G155E (on ENST00000440961; = p.G162E on NM_001199206.3) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV60622489; called by muse, mutect2, varscan2
- KCNAB2 | c.371+1G>T p.X124_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99379254; called by muse, mutect2
- KCNB1 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as rs1391326211, COSV65565804; called by muse, mutect2
- KCNB2 | c.47C>A p.S16* | Nonsense Mutation (SNP) | VAF 34/245 reads (14%) | catalogued as COSV73049534, COSV99074163; called by muse, mutect2, varscan2
- KNDC1 | c.4550C>A p.S1517* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV58831902; called by muse, mutect2, varscan2
- KRT34 | c.291C>A p.S97R | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV67450565; called by muse, mutect2, varscan2
- KRT6A | c.924G>T p.Q308H | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58106341; called by muse, mutect2, varscan2
- LAMA4 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1256506675, COSV57900196; called by muse, mutect2, varscan2
- LAMB1 | c.2000C>A p.P667H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1177576388; called by muse, mutect2, varscan2
- LAMB1 | c.1999C>A p.P667T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV99741920; called by muse, mutect2, varscan2
- LMO7 | c.3624G>T p.W1208C (on ENST00000357063; = p.W889C on NM_005358.5) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1265265325; called by muse, mutect2, varscan2
- LPAR2 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs557003143; called by muse, mutect2
- LRFN5 | c.584A>T p.H195L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs771897354; called by mutect2, varscan2
- LRP1B | c.4558C>A p.H1520N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67275021; called by muse, mutect2, varscan2
- MAEL | c.562C>A p.R188S | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs780212800, COSV63112416; called by muse, mutect2, varscan2
- MAGEB10 | c.971C>A p.A324D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.403); catalogued as COSV100775183; called by muse, mutect2, varscan2
- MAGEC2 | c.280G>C p.G94R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.497); catalogued as COSV56000590; called by muse, mutect2, varscan2
- MCHR2 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759033908, COSV56003651; called by muse, mutect2, varscan2
- MSC | c.535-1G>T p.X179_splice | Splice Site (SNP) | VAF 48/244 reads (20%) | catalogued as COSV57696102; called by muse, mutect2, varscan2
- MTUS1 | c.2650C>T p.R884* (on ENST00000262102 / NM_001363061.1; = p.R50* on NM_020749.4) | Nonsense Mutation (SNP) | VAF 43/131 reads (33%) | catalogued as rs758716363, COSV50595329; called by muse, mutect2, varscan2
- MUC16 | c.39589A>T p.S13197C | Missense Mutation (SNP) | VAF 138/659 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV101109929; called by muse, mutect2, varscan2
- MUC3A | c.7466T>A p.L2489Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0.04); catalogued as rs1420869122; called by muse, mutect2, varscan2
- MYOM1 | c.1333A>G p.R445G | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1567946959; called by muse, mutect2
- NDN | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs1338477724, COSV59358349; called by muse, mutect2
- NEK5 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV62881093; called by muse, mutect2, varscan2
- NEMP1 | c.571G>A p.G191R (on ENST00000300128 / NM_001130963.2; = p.G118R on NM_015257.3) | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009050695; called by muse, mutect2, varscan2
- NME6 | c.217G>A p.V73M (on ENST00000415053; = p.V81M on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1560001033; called by muse, varscan2
- NPAS4 | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV60649590; called by muse, mutect2, varscan2
- NRXN1 | c.2200G>T p.V734F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); catalogued as rs1212867329; called by muse, mutect2, varscan2
- OLFM3 | c.1178G>T p.S393I (on ENST00000338858 / NM_001288821.1; = p.S373I on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs749507316; called by muse, mutect2, varscan2
- OR14J1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs760898355, COSV65845582; called by muse, mutect2, varscan2
- OR2D2 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV55058188; called by muse, mutect2, varscan2
- OR2M3 | c.907A>G p.K303E | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV71759337; called by muse, mutect2
- OR4C11 | c.752C>A p.P251Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56352721; called by muse, mutect2, varscan2
- OR4C16 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58942770; called by muse, mutect2, varscan2
- OR4N5 | c.794T>A p.F265Y | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as COSV61320270; called by muse, mutect2, varscan2
- OR56B4 | c.87del p.W29Cfs*9 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as COSV57204421; called by mutect2, pindel, varscan2
- OR5D16 | c.463G>T p.V155F | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs143345816; called by muse, mutect2, varscan2
- OR5T2 | c.727G>T p.G243C | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs1375233496; called by muse, mutect2, varscan2
- OTUD4 | c.1237C>T p.R413W (on ENST00000447906 / NM_001366057.1; = p.R348W on NM_001102653.1) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs201351864; called by muse, mutect2, varscan2
- P2RY8 | c.855C>A p.N285K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67177995; called by muse, mutect2, varscan2
- PCDH17 | c.3158C>T p.S1053F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs1280587955, COSV64972371; called by muse, mutect2, varscan2
- PCDHB11 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs781883051, COSV61309842; called by muse, mutect2, varscan2
- PCDHB4 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782514436; called by muse, mutect2, varscan2
- PCDHB6 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50689588; called by muse, mutect2, varscan2
- PCDHGB5 | c.1420del p.D474Tfs*6 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as COSV53894274; called by mutect2, pindel, varscan2
- PCED1A | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as rs1174920282; called by muse, mutect2
- PIAS2 | c.1056G>T p.R352S | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749367210; called by muse, mutect2, varscan2
- PLCB1 | c.3232G>T p.E1078* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as rs1231287777, COSV62064376; called by muse, mutect2, varscan2
- POSTN | c.2270-2A>G p.X757_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | catalogued as COSV65714902; called by muse, mutect2, varscan2
- PRDM11 | c.1384T>A p.L462I (on ENST00000530656 / NM_001359633.1; = p.L428I on NM_001256695.1) | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1450335092; called by muse, mutect2, varscan2
- PRDM9 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57013195; called by muse, mutect2, varscan2
- PRKAG3 | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs759701909; called by muse, mutect2
- PTPN14 | c.1018G>T p.V340F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs747090290; called by muse, mutect2, varscan2
- PTPRB | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as rs1396889536, COSV51726186; called by muse, mutect2, varscan2
- PXYLP1 | c.550T>A p.Y184N | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53891818; called by muse, mutect2, varscan2
- RAB30 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52627630; called by muse, mutect2, varscan2
- RALGAPA2 | c.2560G>T p.G854C | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1340036395, COSV52508589; called by muse, mutect2, varscan2
- RASSF9 | c.1086G>T p.K362N | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV100771363; called by muse, mutect2, varscan2
- RB1 | c.2339C>G p.S780* | Nonsense Mutation (SNP) | VAF 33/177 reads (19%) | catalogued as CM058003, COSV57316285; called by muse, mutect2, varscan2
- RIMS2 | c.2912G>T p.R971L (on ENST00000666250 / NM_001348490.2; = p.R779L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51668611, COSV99169380; called by muse, mutect2, varscan2
- RP1L1 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100261516; called by muse, mutect2, varscan2
- RXRA | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763558005; called by muse, mutect2, varscan2
- RYR2 | c.12178C>A p.Q4060K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as COSV100771280; called by muse, mutect2, varscan2
- SEMA4F | c.589G>T p.G197W | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387273660; called by muse, mutect2, varscan2
- SEPSECS | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV100259063; called by muse, mutect2, varscan2
- SERPINB2 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV100208331; called by muse, mutect2, varscan2
- SETBP1 | c.2605A>T p.S869C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56338625; called by muse, mutect2, varscan2
- SGCZ | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); catalogued as rs1228906928; called by muse, mutect2, varscan2
- SIPA1L2 | c.4376C>T p.P1459L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.76); catalogued as rs1337431504; called by muse, mutect2, varscan2
- SLC12A3 | c.2260G>T p.V754L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV52634768; called by muse, mutect2
- SLC22A13 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs751403754; called by muse, mutect2, varscan2
- SLC35F4 | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV60263758; called by muse, mutect2, varscan2
- SLC5A7 | c.582C>A p.C194* | Nonsense Mutation (SNP) | VAF 42/209 reads (20%) | catalogued as rs1455852824; called by muse, mutect2, varscan2
- SLC6A5 | c.877T>C p.Y293H | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1436597760; called by muse, mutect2, varscan2
- SMPD4 | c.2026C>T p.L676F (on ENST00000409031 / NM_017951.4; = p.L647F on NM_017751.4) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1295625303; called by muse, mutect2, varscan2
- SNAP25 | c.481C>A p.R161S | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV54770468, COSV99655334; called by muse, mutect2, varscan2
- SNRNP40 | c.377C>G p.S126* | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99744961; called by muse, mutect2, varscan2
- SPATA31A1 | c.370G>C p.G124R | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99071940; called by muse, mutect2, varscan2
- SPATA31E1 | c.3091G>A p.D1031N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs1447058032; called by muse, mutect2, varscan2
- SPINK5 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56250905; called by muse, mutect2, varscan2
- SPRR2D | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 96/298 reads (32%) | catalogued as COSV64209394; called by muse, varscan2
- STAT6 | c.1117C>G p.R373G | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367603540; called by muse, mutect2, varscan2
- SUSD4 | c.1427G>A p.G476D | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as rs1185484105; called by muse, mutect2, varscan2
- SZT2 | c.5271G>T p.K1757N (on ENST00000634258 / NM_001365999.1; = p.K1700N on NM_015284.4) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.677); catalogued as COSV100987555; called by muse, mutect2, varscan2
- TAFA2 | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 29/44 reads (66%) | catalogued as COSV69190246; called by muse, mutect2, varscan2
- TBC1D5 | c.825G>T p.G275= | Splice Region (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99511902; called by muse, mutect2, varscan2
- TEKT1 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV58623033; called by muse, mutect2, varscan2
- THSD7B | c.3726C>A p.C1242* (on ENST00000272643; = p.C1240* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 43/218 reads (20%) | catalogued as COSV55698170; called by muse, mutect2, varscan2
- TIE1 | c.2393C>G p.T798S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1457894680; called by muse, mutect2, varscan2
- TLL1 | c.2623C>A p.Q875K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1246372772; called by muse, mutect2, varscan2
- TPO | c.1477G>T p.G493C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778515113, CM022475, COSV61094451; called by muse, mutect2, varscan2
- TRAV24 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1441632176; called by muse, mutect2, varscan2
- TRIM58 | c.1074G>A p.W358* | Nonsense Mutation (SNP) | VAF 75/253 reads (30%) | catalogued as rs142321693, COSV100825193; called by muse, mutect2, varscan2
- TTC29 | c.907A>T p.I303F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57275446; called by muse, mutect2, varscan2
- TTN | c.27434G>A p.G9145E (on ENST00000591111; = p.G8218E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | PolyPhen possibly damaging (0.56); catalogued as rs866946485, COSV59953892; called by muse, mutect2, varscan2
- VAT1L | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 32/174 reads (18%) | catalogued as COSV56817993; called by muse, mutect2, varscan2
- VRK1 | c.161-1G>T p.X54_splice | Splice Site (SNP) | VAF 11/53 reads (21%) | catalogued as rs1468679953; called by muse, mutect2, varscan2
- XIRP2 | c.4558C>A p.L1520I (on ENST00000628543; = p.L1695I on NM_152381.6) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV54693569; called by muse, mutect2, varscan2
- XRN1 | c.2979-2A>T p.X993_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as rs1423738731; called by muse, mutect2, varscan2
- ZIC1 | c.273C>G p.S91R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as COSV99292565; called by muse, mutect2, varscan2
- ZNF384 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs968023019, COSV100158254; called by muse, mutect2, varscan2
- A2M | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ABCC3 | c.1383G>T p.L461F | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADAMTS12 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ADRA1B | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.14383G>A p.G4795R | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ALPK1 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- AMACR | c.903G>T p.E301D | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AMY1A | c.996T>G p.D332E | Missense Mutation (SNP) | VAF 46/566 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.043); called by muse, mutect2
- ANK1 | c.5256G>T p.K1752N | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD20A4P | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ANKRD50 | c.1944G>T p.L648F | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKS1B | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AOX1 | c.2235G>T p.M745I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ARR3 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ASPM | c.3204A>T p.E1068D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, mutect2
- ATP11C | c.1915A>G p.I639V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATP2C2 | c.693C>A p.S231R | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- AXDND1 | c.3031G>C p.G1011R | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- AXL | c.1276T>C p.W426R | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- BCL9 | c.2917C>G p.P973A | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- BEND4 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- BRINP3 | c.821dup p.E275Gfs*3 | Frame Shift Ins (INS) | VAF 15/90 reads (17%) | called by mutect2, pindel, varscan2
- CACNA2D4 | c.239G>A p.W80* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- CAGE1 | c.860C>T p.P287L (on ENST00000512086; = p.P151L on NM_205864.3) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2
- CAPN3 | c.34A>G p.R12G | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN7 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CASC3 | c.641A>C p.D214A | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CCDC15 | c.1858C>G p.Q620E | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC39 | c.1209T>A p.F403L | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CCDC80 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- CDC20B | c.1089G>C p.W363C | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH10 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- CDH2 | c.1251C>G p.N417K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- CENPK | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2
- CFAP47 | c.4718C>G p.S1573* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- CHAT | c.1517T>A p.V506E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CNMD | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTN5 | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL15A1 | c.2543T>A p.L848* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | called by muse, mutect2, varscan2
- COL24A1 | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A1 | c.1244C>A p.P415H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.74); called by muse, mutect2
- COL4A5 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- COL4A6 | c.4262G>T p.S1421I | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- COL5A1 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CPQ | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CRNN | c.1181A>G p.E394G | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- CRYGC | c.499T>A p.L167M | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- CTNND2 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP1A1 | c.1079_1080del p.S360* | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2
- CYP26B1 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CYP39A1 | c.411del p.Q138Nfs*2 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel*, varscan2*
- CYP46A1 | c.402G>T p.W134C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX35 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DNAH11 | c.4903G>T p.D1635Y | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- DNAH12 | c.496G>T p.V166F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- DST | c.17080G>T p.A5694S (on ENST00000361203 / NM_001374722.1; = p.A3391S on NM_015548.5) | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- DST | c.14996C>A p.S4999Y (on ENST00000361203 / NM_001374722.1; = p.S2587Y on NM_015548.5) | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- DYNC2H1 | c.2713G>C p.V905L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- DYNC2LI1 | c.299C>G p.P100R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ECEL1 | c.2059T>A p.Y687N | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ECHDC3 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EDIL3 | c.213A>T p.E71D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EGFLAM | c.2595C>A p.F865L (on ENST00000354891 / NM_001205301.2; = p.F857L on NM_152403.4) | Missense Mutation (SNP) | VAF 81/147 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ELMOD1 | c.305T>A p.L102H | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ENG | c.874C>A p.L292I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- EPHB3 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- EPX | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- EZHIP | c.1127C>A p.S376* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- F2RL2 | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM135B | c.2963C>A p.T988N | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FCRL3 | c.938A>T p.Q313L | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- FCRL5 | c.1100A>T p.K367M | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- FNDC8 | c.258C>A p.S86R | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- FOXG1 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- GDAP1L1 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GDPGP1 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- GLG1 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- GMDS | c.904A>C p.N302H | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); called by muse, mutect2
- GNB1 | c.699+1G>C p.X233_splice | Splice Site (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- GPR22 | c.1067C>A p.A356D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPR22 | c.1069T>A p.Y357N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GRXCR1 | c.11G>T p.R4M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPACAM2 | c.131T>C p.V44A (on ENST00000394468 / NM_001039372.4; = p.V32A on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HERC6 | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- HHIPL2 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HNF4G | c.1061T>C p.I354T (on ENST00000354370 / NM_001330561.2; = p.I401T on NM_004133.5) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- HOXA2 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- IGKV1-27 | c.78G>T p.M26I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- IL21R | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- INO80C | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCND3 | c.626C>A p.T209K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNT2 | c.1817G>T p.C606F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- KCNU1 | c.2650C>T p.L884F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIAA1109 | c.12362G>T p.G4121V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KIAA1755 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- KIF20A | c.2002T>G p.S668A | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT31 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- KRTAP12-1 | c.228C>A p.C76* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- LRP1B | c.7922C>A p.T2641K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP1B | c.4030T>A p.W1344R | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MALSU1 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MAP1B | c.2960G>A p.R987K | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPT | c.1565C>T p.S522F (on ENST00000262410 / NM_001377265.1; = p.S447F on NM_016835.4) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MAST4 | c.2162G>T p.S721I (on ENST00000403625 / NM_001164664.2; = p.S532I on NM_015183.3) | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MC3R | c.249dup p.D84Rfs*228 | Frame Shift Ins (INS) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- MLLT3 | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MMADHC | c.879A>T p.L293F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- MMRN1 | c.3138T>A p.S1046R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MS4A1 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 32/136 reads (24%) | called by muse, mutect2, varscan2
- MTERF3 | c.116A>G p.H39R | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTIF2 | c.503+1G>T p.X168_splice | Splice Site (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- MYH4 | c.4318A>T p.N1440Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MYRF | c.1699C>A p.P567T (on ENST00000278836 / NM_001127392.3; = p.P558T on NM_013279.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- NAV3 | c.488-2A>T p.X163_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- NEBL | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- NLRP4 | c.1745A>C p.D582A | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- NOS2 | c.1653G>T p.E551D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- NR1H3 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP214 | c.4485G>T p.E1495D | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR2M3 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 86/250 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2
- OR2M5 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 105/368 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- OR2T4 | c.348C>G p.D116E | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- OR4C16 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- OR4D1 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR4K15 | c.439T>A p.Y147N (on ENST00000305051; = p.Y123N on NM_001005486.1) | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- OR56A3 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- OR5K1 | c.725C>A p.A242E | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR6C6 | c.699C>G p.N233K | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OVCH1 | c.2177G>T p.R726I | Missense Mutation (SNP) | VAF 126/239 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- OXA1L | c.786G>T p.M262I (on ENST00000285848; = p.M202I on NM_005015.5) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- P2RY10 | c.586G>C p.V196L | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PAK3 | c.526G>T p.A176S (on ENST00000262836 / NM_001324328.2; = p.A161S on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAPLN | c.1795C>A p.Q599K (on ENST00000554301; = p.Q572K on NM_173462.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2
- PCLO | c.13559G>T p.G4520V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDS5A | c.3827C>G p.S1276C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- PEG3 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PHGDH | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PIAS2 | c.1055G>T p.R352M | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIK3C3 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCD4 | c.684G>T p.L228F | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- PLPPR4 | c.328A>T p.M110L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLS3 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PPM1L | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PRAMEF12 | c.459C>A p.F153L | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR16 | c.598G>C p.G200R (on ENST00000407149 / NM_001300783.2; = p.G177R on NM_016644.2) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PTHLH | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRD | c.1948A>C p.T650P | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PTPRH | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PTPRN2 | c.920T>A p.I307N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, varscan2
- PTPRT | c.2245G>T p.G749C | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RABEP1 | c.675_676delinsT p.E225Dfs*10 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by pindel, varscan2*
- RBM47 | c.557G>C p.S186T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- RC3H1 | c.1680G>T p.R560S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RCN3 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RFTN2 | c.395C>A p.S132Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF128 | c.517A>C p.N173H (on ENST00000255499 / NM_194463.2; = p.N147H on NM_024539.3) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- RXRG | c.1167G>C p.E389D | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RYR3 | c.5663G>T p.C1888F | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- SARS1 | c.141A>T p.R47S | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- SCN7A | c.4473C>A p.Y1491* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- SCN9A | c.22G>T p.G8* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- SEC61A2 | c.1119_1124del p.F374_F375del | In Frame Del (DEL) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- SHPRH | c.1704G>T p.K568N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SLC20A1 | c.1477A>G p.R493G | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SLC22A16 | c.454T>A p.W152R | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC25A36 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); called by muse, mutect2
- SLC47A1 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SLC6A15 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC8A1 | c.2501C>G p.S834C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLIT2 | c.1589A>T p.H530L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLK | c.2633T>G p.I878S | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLTM | c.2835+1G>T p.X945_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- SOX6 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SPTBN4 | c.1766A>T p.E589V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SRCAP | c.6783G>T p.K2261N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SRSF11 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SYMPK | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, varscan2
- TENM4 | c.7189C>G p.Q2397E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.93); called by muse, mutect2
- TEX15 | c.2225G>C p.S742T (on ENST00000256246; = p.S1125T on NM_001350162.2) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TKTL1 | c.385T>C p.S129P | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- TMEM200A | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM47 | c.360T>A p.F120L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMX2 | c.399G>C p.M133I | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRBV5-1 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TRPV6 | c.1462A>G p.S488G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.06); called by muse, mutect2
- TTN | c.15894G>A p.M5298I (on ENST00000591111; = p.M4371I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/175 reads (15%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNDC16 | c.11G>C p.G4A | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UBXN10 | c.832G>T p.G278W | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- UGT2B10 | c.1289C>G p.T430R | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- UNC13A | c.4468G>T p.D1490Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- UNC79 | c.1524+1G>C p.X508_splice (on ENST00000393151 / NM_001346218.2; = p.X331_splice on NM_020818.5) | Splice Site (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- UPF2 | c.3768G>T p.K1256N | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- USP6NL | c.1561G>T p.G521C | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- USP9Y | c.7053del p.W2351Cfs*39 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | called by mutect2, pindel, varscan2
- UTP14C | c.533_534delinsT p.K178Mfs*21 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | called by pindel, varscan2*
- XRN2 | c.2657G>T p.G886V | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- YY2 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- ZBTB40 | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- ZC2HC1C | c.413C>A p.A138E | Missense Mutation (SNP) | VAF 70/311 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZFAT | c.3124A>T p.K1042* | Nonsense Mutation (SNP) | VAF 13/149 reads (9%) | called by muse, mutect2
- ZFHX4 | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); called by muse, mutect2
- ZFP37 | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZMYND11 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ZNF165 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- ZNF283 | c.1325G>T p.R442L | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ZNF438 | c.2245G>T p.G749* | Nonsense Mutation (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- ZNF618 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- A4GNT | c.6G>A p.R2= | Silent (SNP) | VAF 28/103 reads (27%) | called by muse, mutect2, varscan2
- ACTR8 | c.585A>T p.P195= | Silent (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- ADGRG4 | c.1215A>C p.S405= | Silent (SNP) | VAF 117/381 reads (31%) | called by muse, mutect2, varscan2
- ADRA2B | c.780G>A p.E260= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV69787918; called by muse, mutect2
- ALPK1 | c.1050G>A p.E350= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- ASH1L | c.6993G>A p.E2331= (on ENST00000368346 / NM_001366177.2; = p.E2326= on NM_018489.3) | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV100853483; called by muse, mutect2, varscan2
- ASIC2 | c.648G>T p.G216= | Silent (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- ASIP | c.90C>A p.L30= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs1310256167; called by muse, mutect2, varscan2
- BOD1L1 | c.4734A>G p.A1578= | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- BPIFC | c.390G>T p.G130= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV55912190; called by muse, mutect2, varscan2
- C2orf16 | c.5031C>T p.S1677= | Silent (SNP) | VAF 30/186 reads (16%) | catalogued as rs755242682, COSV62676914; called by muse, mutect2, varscan2
- C6orf15 | c.123G>T p.G41= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as rs749736144, COSV99457267; called by muse, mutect2, varscan2
- C9 | c.714T>G p.A238= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV54677305; called by muse, mutect2, varscan2
- CASR | c.1746C>T p.L582= (on ENST00000490131; = p.L659= on NM_000388.4) | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- CDH10 | c.1744C>T p.L582= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- CDH9 | c.771G>T p.T257= | Silent (SNP) | VAF 72/161 reads (45%) | catalogued as rs141361996; called by muse, mutect2, varscan2
- CFAP69 | c.234T>C p.Y78= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- CLDN22 | c.231C>A p.L77= | Silent (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- CORO6 | c.828C>A p.P276= | Silent (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- CPNE6 | c.228C>A p.A76= | Silent (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- CUTC | c.627A>T p.L209= | Silent (SNP) | VAF 80/281 reads (28%) | called by muse, mutect2, varscan2
- DCAF17 | c.606G>T p.G202= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100266300, COSV59830552; called by muse, mutect2
- DCHS1 | c.7009C>T p.L2337= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs752426531; called by muse, mutect2, varscan2
- DIDO1 | c.1827A>T p.S609= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- DNAH11 | c.9108G>T p.V3036= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, varscan2
- DYSF | c.921C>A p.T307= | Silent (SNP) | VAF 21/143 reads (15%) | called by muse, mutect2, varscan2
- EDIL3 | c.693C>G p.T231= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- EGR2 | c.444C>T p.P148= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs1411187953; called by muse, mutect2, varscan2
- FAM107A | c.301C>T p.L101= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV62980825; called by muse, mutect2, varscan2
- FAM135B | c.1773G>T p.G591= | Silent (SNP) | VAF 51/193 reads (26%) | catalogued as COSV52716916; called by muse, mutect2, varscan2
- FGD5 | c.2538G>A p.E846= | Silent (SNP) | VAF 51/189 reads (27%) | catalogued as rs1308478567; called by muse, mutect2, varscan2
- FGG | c.918C>T p.Y306= | Silent (SNP) | VAF 37/154 reads (24%) | called by muse, mutect2, varscan2
- FLNC | c.5376G>T p.A1792= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV57957566; called by muse, mutect2
- FUT4 | c.1302G>A p.G434= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs1405115297, COSV62469420; called by muse, mutect2, varscan2
- GFRA3 | c.991C>T p.L331= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV51231627; called by muse, mutect2, varscan2
- GPR85 | c.771G>T p.L257= | Silent (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- GRAMD1C | c.1725G>A p.L575= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs751032736; called by muse, mutect2, varscan2
- GRIA1 | c.1914G>T p.L638= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV53592025; called by muse, mutect2, varscan2
- HCN3 | c.762C>T p.L254= | Silent (SNP) | VAF 22/171 reads (13%) | called by muse, mutect2, varscan2
- HEPH | c.2331G>T p.L777= (on ENST00000343002; = p.L510= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100295095; called by muse, mutect2, varscan2
- HFM1 | c.525G>T p.G175= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- HHIPL2 | c.648G>C p.L216= | Silent (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- HYDIN | c.1797C>T p.Y599= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs760517494; called by mutect2, varscan2
- IQGAP1 | c.4503C>T p.A1501= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs750054244, COSV99184978; called by muse, mutect2, varscan2
- ITGA8 | c.792C>T p.D264= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as rs1217396016, COSV100959144; called by muse, mutect2, varscan2
- KCNK2 | c.237G>C p.V79= (on ENST00000444842 / NM_001017425.3; = p.V64= on NM_014217.4) | Silent (SNP) | VAF 34/122 reads (28%) | called by muse, mutect2, varscan2
- KCNU1 | c.1182A>C p.A394= | Silent (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- KIAA1109 | c.12363A>T p.G4121= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2
- KRT1 | c.1086C>A p.A362= | Silent (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- KRT33B | c.840T>C p.N280= | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as rs377003814; called by muse, mutect2
- KYNU | c.1119G>A p.K373= | Silent (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.1080G>T p.L360= (on ENST00000418998 / NM_001377303.1; = p.L270= on NM_015478.7) | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs1425653453; called by muse, mutect2, varscan2
- LCE2A | c.174C>A p.G58= | Silent (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- LRP1B | c.1140C>A p.V380= | Silent (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- LRRN3 | c.693C>A p.A231= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV57822579; called by muse, mutect2, varscan2
- MKNK1 | c.414G>C p.V138= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- MKRN3 | c.456G>T p.P152= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100091899; called by muse, mutect2
- MKS1 | c.735C>T p.L245= | Silent (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- MMP13 | c.954G>T p.A318= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs759581047, COSV52826190; called by muse, mutect2, varscan2
- MYH15 | c.5271G>T p.V1757= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- NBAS | c.4839G>T p.V1613= | Silent (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- NDST2 | c.942G>A p.L314= | Silent (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- NID1 | c.1620C>A p.I540= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV51617847, COSV51627631; called by muse, mutect2
- NKX3-1 | c.459A>G p.E153= | Silent (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- NLRP4 | c.519G>T p.S173= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV56709907; called by muse, mutect2, varscan2
- NR0B1 | c.486G>A p.A162= | Silent (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- NUP133 | c.459C>T p.A153= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs758159337, COSV54572888; called by muse, mutect2, varscan2
- OR10J3 | c.345G>T p.L115= | Silent (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- OR10R2 | c.459C>G p.P153= | Silent (SNP) | VAF 56/172 reads (33%) | catalogued as rs1290992428; called by muse, mutect2, varscan2
- OR2S2 | c.405G>T p.V135= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- OR52A1 | c.144G>A p.L48= | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- OR5L1 | c.144G>C p.L48= | Silent (SNP) | VAF 41/203 reads (20%) | called by muse, mutect2, varscan2
- OR8J1 | c.234C>A p.A78= | Silent (SNP) | VAF 23/108 reads (21%) | called by muse, mutect2, varscan2
- PARD3B | c.2698C>T p.L900= (on ENST00000406610 / NM_001302769.2; = p.L831= on NM_057177.7) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1377137850; called by muse, mutect2
- PCDHA7 | c.1875G>T p.G625= | Silent (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.180G>T p.A60= | Silent (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.96G>T p.L32= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- PIKFYVE | c.4824G>T p.G1608= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- PKNOX2 | c.306C>T p.S102= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as rs763656834, COSV53540862, COSV53546772; called by muse, mutect2, varscan2
- POLE | c.1278G>A p.A426= | Silent (SNP) | VAF 45/230 reads (20%) | catalogued as rs1437075270; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP1R17 | c.162G>A p.L54= | Silent (SNP) | VAF 74/317 reads (23%) | called by muse, mutect2, varscan2
- PRRC2C | c.3375C>T p.N1125= (on ENST00000367742; = p.N1123= on NM_015172.4) | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- REG1A | c.261G>A p.L87= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as COSV52070268; called by muse, mutect2, varscan2
- RFX3 | c.1302G>T p.G434= | Silent (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- RGS4 | c.498C>G p.R166= | Silent (SNP) | VAF 144/396 reads (36%) | catalogued as COSV100905613; called by muse, mutect2, varscan2
- RP1L1 | c.4488C>A p.T1496= | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- RYR2 | c.5043T>C p.D1681= | Silent (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- SAMD9 | c.336A>G p.Q112= | Silent (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- SDK1 | c.1857G>T p.S619= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV67362478; called by muse, mutect2, varscan2
- SEMA3A | c.2188C>A p.R730= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV54865282; called by muse, mutect2, varscan2
- SEPTIN6 | c.702G>T p.P234= | Silent (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- SIGLEC8 | c.438G>C p.L146= | Silent (SNP) | VAF 22/124 reads (18%) | called by muse, mutect2, varscan2
- SLC5A8 | c.1029C>T p.A343= | Silent (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- SLIT2 | c.4329G>T p.T1443= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- SLITRK5 | c.894G>A p.T298= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs1320711553; called by muse, mutect2, varscan2
- SPANXN3 | c.264C>T p.G88= | Silent (SNP) | VAF 146/585 reads (25%) | catalogued as rs782242814, COSV100980861, COSV65140598; called by muse, mutect2, varscan2
- SPHKAP | c.4074T>C p.S1358= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- SREK1IP1 | c.297C>T p.S99= | Silent (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- ST3GAL2 | c.915C>A p.G305= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs769949904; called by mutect2, varscan2
- SYN2 | c.1101G>T p.L367= | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- TANK | c.750A>G p.P250= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as rs1262422085; called by muse, mutect2, varscan2
- THBS4 | c.1437C>A p.A479= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- TMEM130 | c.906C>A p.T302= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- TRPM6 | c.5652G>T p.R1884= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- TULP1 | c.768T>A p.A256= | Silent (SNP) | VAF 63/294 reads (21%) | called by muse, mutect2
- TYMS | c.519C>T p.D173= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as rs770269195, COSV51892510; called by muse, mutect2
- USH2A | c.9600C>A p.P3200= | Silent (SNP) | VAF 31/105 reads (30%) | called by muse, varscan2
- UST | c.279A>T p.P93= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as COSV100819765; called by muse, mutect2, varscan2
- VRTN | c.978G>T p.R326= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs765480679; called by muse, mutect2, varscan2
- ZNF98 | c.1572C>A p.G524= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- C1QTNF7 | c.*2C>A | 3'UTR (SNP) | VAF 12/67 reads (18%) | catalogued as rs1453323106, COSV99765026; called by muse, mutect2, varscan2
- DENND1B | c.83-20512A>T | Intron (SNP) | VAF 16/46 reads (35%) | catalogued as rs921398917; called by muse, mutect2, varscan2
- FCAR | c.-1G>C | 5'UTR (SNP) | VAF 38/89 reads (43%) | catalogued as COSV62029038; called by muse, mutect2, varscan2
- MAP3K20 | c.987+4065del | Intron (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- MIR1-1HG-AS1 | n.662G>T | RNA (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-48043T>A | Intron (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-48042T>A | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2
- SNORD115-2 | n.1G>T | RNA (SNP) | VAF 8/30 reads (27%) | catalogued as rs1208565089; called by muse, mutect2, varscan2
- SNORD115-38 | n.73G>T | RNA (SNP) | VAF 23/91 reads (25%) | catalogued as rs777075182; called by muse, mutect2, varscan2
- TCP10L3 | n.502C>A | RNA (SNP) | VAF 8/47 reads (17%) | catalogued as rs1172365978; called by muse, mutect2, varscan2
- TMEM183B | n.679A>T | RNA (SNP) | VAF 55/276 reads (20%) | called by muse, mutect2, varscan2
- TRAC | c.*136C>A | 3'UTR (SNP) | VAF 69/263 reads (26%) | catalogued as rs1388133541; called by muse, varscan2
- UBTFL2 | n.762G>A | RNA (SNP) | VAF 11/119 reads (9%) | catalogued as rs1344005783; called by muse, varscan2
- WNT3A | c.*785C>A | 3'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
